Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HE, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HE-01A (Primary Tumor).

Synoptic translated report

Site : Left lung superior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 5.0 x 5.0 cm

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Moderately to poorly differentiated squamous cell carcinoma

Node status : N 1(4/34)

TNM : pT2 pN1 (4/34) G2-3 R0

ICD-O-3

Carcinoma, Squamous cell NOS
8070/3

Site: ① Lung, upper lobe
c34.1

JW 2/1/13

Pathologist signature:

Date:

Prior Malignancy History	OMF-OK	✓

Source: NCI Genomic Data Commons file b8192fb6-c301-4e45-8918-2d7632500fee (TCGA-NC-A5HE.4845C8ED-6B22-4B64-A05E-48D5A7064797.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).